Somatic mutation profile of tumor specimen TCGA-DA-A1IB-06A (aliquot TCGA-DA-A1IB-06A-11D-A196-08) from TCGA case TCGA-DA-A1IB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.1 years (25,252 days).
Specimen TCGA-DA-A1IB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52ee8420-8fe1-4551-8e9a-89efc0a65644.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1IB-10A (Blood Derived Normal), aliquot TCGA-DA-A1IB-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88ddfd29-f7aa-4caf-85a7-ced028b04e82

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAMLD1 | c.1981G>C p.G661R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.295); catalogued as COSV99475459; called by muse, mutect2
- PLEKHS1 | c.623A>C p.H208P (on ENST00000369310 / NM_182601.1; = p.H214P on NM_024889.5) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV63056371; called by muse, mutect2
- USH2A | c.10665G>T p.E3555D | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56408896; called by mutect2, varscan2
- BEGAIN | c.1401C>G p.L467= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV62069625; called by mutect2, varscan2
- MIR1246 | n.10G>T | RNA (SNP) | VAF 8/86 reads (9%) | called by mutect2, varscan2
